Somatic mutation profile of tumor specimen TCGA-HV-AA8X-01A (aliquot TCGA-HV-AA8X-01A-11D-A397-08) from TCGA case TCGA-HV-AA8X, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.7 years (27,662 days).
Specimen TCGA-HV-AA8X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40af8ced-3998-4c7d-b73b-42d7df60440b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-AA8X-10A (Blood Derived Normal), aliquot TCGA-HV-AA8X-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c231f883-64d8-4e9c-b32c-6b60f7022ec2

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Splice Site 3, Frame Shift Del 2, Intron 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/235 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 45/113 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776044877, COSV100716941; called by muse, mutect2, varscan2
- ASB15 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 93/363 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs370081452; called by muse, mutect2, varscan2
- C16orf74 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs377716191, COSV99411667; called by muse, varscan2
- CACNA1G | c.904T>C p.Y302H | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV100661100; called by muse, mutect2, varscan2
- CCNO | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1399260642, COSV99248069; called by muse, mutect2, varscan2
- DMXL1 | c.3228G>T p.M1076I | Missense Mutation (SNP) | VAF 60/397 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100223154; called by muse, mutect2, varscan2
- DPP10 | c.78C>A p.S26R | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs1216991225, COSV100058095, COSV59710202; called by muse, mutect2, varscan2
- FN1 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100115782; called by muse, mutect2, varscan2
- GALNT18 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs1054356967, COSV57149709; called by muse, mutect2, varscan2
- GDPD4 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as rs367777591; called by muse, mutect2, varscan2
- KSR2 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.718); catalogued as COSV100194117; called by muse, mutect2, varscan2
- MYO3A | c.2338C>A p.L780M | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99778109; called by muse, mutect2, varscan2
- NEB | c.13589C>T p.A4530V | Missense Mutation (SNP) | VAF 205/836 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs375357016, COSV51398511; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NEK10 | c.356T>A p.I119K | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs1437290303, COSV100411335; called by muse, mutect2, varscan2
- NOP2 | c.791C>T p.S264F (on ENST00000322166 / NM_001258308.2; = p.S260F on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1483988669, COSV100444587; called by muse, mutect2, varscan2
- NPAS3 | c.2578G>A p.G860S (on ENST00000356141 / NM_001164749.2; = p.G828S on NM_022123.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs868500866, COSV100639467; called by muse, mutect2, varscan2
- NR2F1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1352107740, COSV100504532; called by muse, mutect2, varscan2
- OSBPL1A | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.986); catalogued as rs1262069827, COSV100111064; called by muse, varscan2
- OSBPL1A | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 96/464 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV100111066; called by muse, varscan2
- OSBPL8 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 64/150 reads (43%) | catalogued as rs1208698899, COSV99674427; called by muse, mutect2, varscan2
- RBM17 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101158995; called by muse, mutect2
- RERE | c.4213C>T p.R1405C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs368040659; called by muse, mutect2
- ROBO3 | c.3922G>A p.V1308M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs752717878, COSV60624157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A11 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1366479866, COSV100762652; called by muse, mutect2
- STAB1 | c.5636G>A p.R1879Q | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs749031768, COSV58732650, COSV58735070; called by muse, mutect2, varscan2
- TMEM200A | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51654106; called by muse, mutect2, varscan2
- TTN | c.8380+1G>A p.X2794_splice (on ENST00000591111; = p.X2748_splice on NM_003319.4) | Splice Site (SNP) | VAF 12/398 reads (3%) | catalogued as rs794729306; ClinVar: uncertain significance; called by muse, mutect2
- TUBA1B | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368270583, COSV60137898; called by muse, mutect2, varscan2
- UBR2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV65768409; called by muse, mutect2, varscan2
- VWA3B | c.3767G>A p.R1256H | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.009); catalogued as rs1189775076, COSV71366941; called by muse, mutect2, varscan2
- ZFYVE16 | c.3199C>G p.L1067V | Missense Mutation (SNP) | VAF 114/445 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100566171; called by muse, mutect2, varscan2
- ZNF98 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); catalogued as COSV100757277; called by mutect2, varscan2
- INPP5F | c.587_590dup p.D197Efs*11 | Frame Shift Ins (INS) | VAF 118/511 reads (23%) | called by mutect2, pindel, varscan2
- KDM6A | c.4176+1_4176+10del p.X1392_splice | Splice Site (DEL) | VAF 47/219 reads (21%) | called by mutect2, pindel, varscan2
- MYH7B | c.5482del p.E1828Nfs*3 | Frame Shift Del (DEL) | VAF 77/297 reads (26%) | called by mutect2, pindel, varscan2
- PNLIP | c.986dup p.D329Efs*2 | Frame Shift Ins (INS) | VAF 103/393 reads (26%) | called by mutect2, pindel, varscan2
- RAB3A | c.333_347+14del p.X111_splice | Splice Site (DEL) | VAF 46/330 reads (14%) | called by mutect2, pindel
- RPRD2 | c.2353del p.S785Lfs*29 | Frame Shift Del (DEL) | VAF 90/215 reads (42%) | called by mutect2, pindel, varscan2
- CAND2 | c.1038C>T p.D346= (on ENST00000456430 / NM_001162499.2; = p.D253= on NM_012298.3) | Silent (SNP) | VAF 73/157 reads (46%) | catalogued as COSV99928552; called by muse, mutect2, varscan2
- CATSPERE | c.1101G>A p.K367= | Silent (SNP) | VAF 14/424 reads (3%) | catalogued as COSV63676448; called by muse, mutect2
- HOXA5 | c.480G>A p.A160= | Silent (SNP) | VAF 200/557 reads (36%) | catalogued as rs202017218, COSV56073789; called by muse, mutect2, varscan2
- IL4I1 | c.210C>T p.A70= | Silent (SNP) | VAF 38/798 reads (5%) | catalogued as rs753062978, COSV62011940; called by muse, mutect2
- MAPK15 | c.1479G>A p.P493= | Silent (SNP) | VAF 163/505 reads (32%) | catalogued as rs369868387; called by muse, mutect2, varscan2
- OR4K17 | c.786C>T p.F262= | Silent (SNP) | VAF 74/178 reads (42%) | catalogued as rs374355972; called by muse, mutect2, varscan2
- OSBPL1A | c.801G>A p.R267= | Silent (SNP) | VAF 208/486 reads (43%) | catalogued as rs367725053; called by muse, mutect2, varscan2
- PCARE | c.288C>T p.T96= | Silent (SNP) | VAF 199/621 reads (32%) | catalogued as COSV100527279; called by muse, mutect2, varscan2
- RPAP1 | c.3192G>A p.S1064= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as rs994645836, COSV100426903; called by muse, mutect2, varscan2
- SLFN13 | c.888C>A p.T296= | Silent (SNP) | VAF 150/890 reads (17%) | catalogued as rs372414173; called by muse, mutect2, varscan2
- SOX11 | c.753G>A p.P251= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1361239969, COSV100430725; called by muse, mutect2
- TPPP3 | c.468C>T p.D156= | Silent (SNP) | VAF 93/324 reads (29%) | catalogued as rs137924465; called by muse, mutect2, varscan2
- TSEN34 | c.663C>T p.Y221= | Silent (SNP) | VAF 51/297 reads (17%) | catalogued as COSV99824572; called by muse, mutect2, varscan2
- DLG3 | c.1773+820G>A | Intron (SNP) | VAF 46/154 reads (30%) | catalogued as rs181757438, COSV52086061; called by muse, mutect2, varscan2
- TRIM36 | c.64-7410G>A | Intron (SNP) | VAF 107/327 reads (33%) | catalogued as COSV99142240; called by muse, mutect2, varscan2
- TXNRD3 | n.702C>A | RNA (SNP) | VAF 61/236 reads (26%) | catalogued as rs1341802759, COSV101274989; called by muse, mutect2, varscan2
